Somatic mutation profile of tumor specimen TCGA-CR-7397-01A (aliquot TCGA-CR-7397-01A-11D-2012-08) from TCGA case TCGA-CR-7397, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 44.8 years (16,351 days).
Specimen TCGA-CR-7397-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f12c73c-8614-4936-bc22-0d7e458c291a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7397-10A (Blood Derived Normal), aliquot TCGA-CR-7397-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08ebd1fd-e8f0-499c-b6ea-a924e410cae0

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 16, Silent 12, Nonsense Mutation 3, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs758570790, COSV67215430; called by muse, mutect2, varscan2
- AOC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100710881; called by muse, mutect2
- AP5M1 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99841295; called by muse, mutect2
- CADPS2 | c.1355C>G p.S452C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as COSV100464648; called by muse, mutect2, varscan2
- CDHR2 | c.3654-1G>A p.X1218_splice | Splice Site (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99991948; called by muse, mutect2, varscan2
- EML5 | c.3305C>G p.S1102C | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100715995; called by muse, mutect2
- GLI2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374155310, CM107450; called by muse, mutect2, varscan2
- KATNIP | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99851649; called by muse, mutect2
- MUTYH | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs373766973; ClinVar: uncertain significance; called by muse, mutect2
- NCK2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.067); catalogued as COSV51888426, COSV51892997; called by muse, mutect2, varscan2
- NKAP | c.342G>A p.W114* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV101004268, COSV65056426; called by muse, mutect2, varscan2
- NPY5R | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as COSV100642867; called by muse, mutect2, varscan2
- PLA2G4C | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV62784424; called by muse, mutect2
- STAM2 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs137997902; called by muse, mutect2, varscan2
- TRPV1 | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as rs746916337, COSV99440271; called by mutect2, varscan2
- TXLNB | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV100625105; called by muse, mutect2
- VCAN | c.3872C>G p.T1291R | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99426704; called by muse, mutect2, varscan2
- VWA7 | c.1346C>G p.S449* | Nonsense Mutation (SNP) | VAF 4/76 reads (5%) | catalogued as COSV100991927; called by muse, mutect2
- WDR48 | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100176778; called by muse, mutect2, varscan2
- ZNF473 | c.856C>G p.H286D | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99569005; called by muse, mutect2
- AUTS2 | c.1812A>G p.Q604= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100718839; called by muse, mutect2
- DNAJB2 | c.36A>T p.R12= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100339049; called by muse, mutect2, varscan2
- HERC2 | c.228G>A p.L76= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV99875567; called by muse, mutect2, varscan2
- KCNJ12 | c.1212C>T p.L404= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100055613, COSV59173117; called by muse, mutect2, varscan2
- KDM3B | c.2395C>T p.L799= | Silent (SNP) | VAF 30/245 reads (12%) | catalogued as COSV100070006; called by muse, mutect2, varscan2
- KLHL24 | c.756G>A p.L252= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1420858788, COSV54429601; called by muse, varscan2
- OR2L13 | c.864C>A p.I288= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100813852; called by muse, mutect2, varscan2
- PTCH1 | c.3015G>T p.G1005= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV100109412; called by muse, mutect2, varscan2
- RINL | c.624C>T p.H208= (on ENST00000591812 / NM_001195833.2; = p.H94= on NM_198445.4) | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs377414672, COSV61575855; called by muse, mutect2, varscan2
- SGIP1 | c.1800A>G p.R600= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV99392310; called by muse, mutect2
- ZBTB18 | c.1269C>T p.Y423= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as COSV100700181; called by muse, mutect2
- ZNF675 | c.1542C>T p.G514= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs370219307; called by muse, mutect2, varscan2
